Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A7C5, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A7C5-01A (Primary Tumor).

[page 1 of 2]
Referred:

Collected:

Tested:

Reported:

Referred by:

Lab No:

CLINICAL INFORMATION

h/o left parietal tumour. If it is an oligo please get 1p19q status.

MACROSCOPIC EXAMINATION

Labelled "Brain tumour".

Specimen consists of two irregular pieces of soft to firm cream tissue measuring 7x5x2mm and 19x10x6mm.

MICROSCOPIC DESCRIPTION

Sections show brain tissue with focal areas of increased cellularity and in some of these areas there are vacuolated cells (abundant cytoplasm) with central nuclei and slightly pleomorphic hyperchromatic nuclei seen (high mitotic count is seen in some areas up to 4/HPF x40). I think it is consistent with oligodendrogliotic cells mixed with astrocytic cells. The adjacent brain tissue also shows a slight increase in cellularity although there is less pleomorphism in this and no fried egg like areas. There is no evidence of necrosis. There are also branching networks of capillary seen.

The GFAP certainly demonstrated a network of astrocytic cells however in the oligodendrogliotic area the stromal clear cell in the centre of this fibrillary network leaving the clear cells unstained and the Ki-67 shows focal area of high index 5-10% and in other areas is <4%.

I think the overall features are that of mixed astrocytic oligodendroglioma.

I would probably grade this as Grade III (WHO grading) and the sections are also sent for 1p19q status.

agrees.

CONCLUSION

BRAIN TUMOUR.

-- MIXED HIGH GRADE OLIGODENDROGLIOMA WITH THE PRESENCE OF
ASTROCYTOMA WHO GRADING, GRADE III.

GLF ICD-O-3

Oligoastrocytoma, grade II
path 9382/3

Oligoastrocytoma, grade III
GLF 9382/3

Site Brain, supratentorial NOS
C71.0

④ Brain, parietal C71.2

QJ 9/25/13

[page 2 of 2]
Lab No:
Date Received
ID Check:
Final Date:
Histology
Cc:

DOB:

Specimen:
Material from:
Referral Diagnosis: Mixed High Grade Oligodendroglioma with Astrocytoma
Review Diagnosis: Oligoastrocytoma (WHO II)
Test Requested: FISH for 1p & 19q deletions & 7/EGFR amplification

Result:
Number of Cells Scored: 218 cells across 10 sites

1p36/1q25 Ratio: 0.62
19q13/19p13 Ratio: 0.65

Conclusion: 1p36 - Loss Detected
19q13-Loss Detected

REFERENCE CRITERIA

1p36 / 1q25 Ratio	< 0.8	- Loss of 1p
19q13 / 19p13 Ratio	< 0.8	- Loss of 19p
EGFR / CEP 7	> 2.2	- Amplified
	< 1.8	- Not Amplified

Probe Manufacturer:

HPV Discrepancy		✓
Genetic/Pathology History		✓
Diagnosis/Synchronous Primary Disease		✓

Source: NCI Genomic Data Commons file b64450c2-8f3f-4470-8e0d-350ed00580aa (TCGA-TM-A7C5.CEA3E51F-5E16-4778-9684-C670C8E4DC8E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).